Somatic mutation profile of tumor specimen TCGA-19-2620-01A (aliquot TCGA-19-2620-01A-01D-1495-08) from TCGA case TCGA-19-2620, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.3 years (25,665 days).
Specimen TCGA-19-2620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d921e21d-eaf0-4c41-b9c3-c99f9d22a081.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2620-10A (Blood Derived Normal), aliquot TCGA-19-2620-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa35bff0-d512-4012-91b7-1757d531c654

The open-access MAF lists 69 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 16, Nonsense Mutation 5, Frame Shift Del 2, Intron 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 276/2263 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1530G>C p.Q510H | Missense Mutation (SNP) | VAF 58/189 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs397507550, CM117756, COSV61005626, COSV61006865; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.2437C>T p.R813* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV67132463; called by muse, mutect2, varscan2
- ADGRD1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs535355861, COSV55439160; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.3943G>A p.G1315R | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV51851544; called by muse, mutect2, varscan2
- ARFGAP1 | c.168C>A p.L56= | Splice Region (SNP) | VAF 28/72 reads (39%) | catalogued as COSV62263435; called by muse, varscan2
- AS3MT | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 89/172 reads (52%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.839); catalogued as rs756399134, COSV54917639; called by muse, mutect2, varscan2
- BCHE | c.107C>A p.T36K | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52256885; called by muse, mutect2, varscan2
- CACNA2D1 | c.2411G>A p.G804E (on ENST00000356253 / NM_001366867.1; = p.G792E on NM_000722.4) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as COSV62383564; called by muse, mutect2, varscan2
- CCDC158 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 46/158 reads (29%) | catalogued as rs755862671, COSV66356514; called by muse, mutect2, varscan2
- CDH9 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV50322416; called by muse, mutect2, varscan2
- DNAH10 | c.9742G>A p.V3248M (on ENST00000409039; = p.V3187M on NM_207437.3) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571654959, COSV68996371; called by muse, mutect2, varscan2
- DNAH7 | c.4339C>G p.L1447V | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56772316; called by muse, mutect2, varscan2
- ENPP5 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751242857, COSV57909145; called by muse, mutect2, varscan2
- EPHA7 | c.2611G>C p.D871H | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.674); catalogued as COSV65186253; called by muse, mutect2, varscan2
- GABRA6 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs145469537, COSV50878218, COSV50884934; called by muse, mutect2, varscan2
- GHSR | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs121917883, CM061011, COSV53840296; called by muse, mutect2, varscan2
- HMCN1 | c.8776C>T p.R2926* | Nonsense Mutation (SNP) | VAF 43/130 reads (33%) | catalogued as rs142475663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF2BP1 | c.911A>C p.Q304P | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV51733041; called by muse, mutect2, varscan2
- IGHV3-7 | c.155G>A p.W52* | Nonsense Mutation (SNP) | VAF 88/298 reads (30%) | catalogued as rs782787393; called by muse, mutect2, varscan2
- IL1RL1 | c.782T>C p.F261S | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV52117911; called by muse, mutect2, varscan2
- LAMA1 | c.4417G>A p.D1473N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as rs756779273, COSV67537471; called by muse, mutect2, varscan2
- LARP1 | c.2792T>A p.M931K (on ENST00000518297 / NM_033551.3; = p.M854K on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV60428579; called by muse, mutect2
- LGSN | c.402A>T p.E134D | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); catalogued as COSV65727663; called by muse, mutect2, varscan2
- LPIN1 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs375865167; called by muse, mutect2, varscan2
- LRP2 | c.6283C>T p.R2095* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as rs753549113, COSV55544116; called by muse, mutect2, varscan2
- LRRC8B | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV58375842; called by muse, mutect2, varscan2
- LTBP2 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.51); catalogued as rs1014407298, COSV56210238; called by muse, mutect2, varscan2
- MAP3K4 | c.730A>G p.R244G | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.285); catalogued as COSV62335445; called by muse, mutect2, varscan2
- MDGA2 | c.2218T>C p.Y740H (on ENST00000399232 / NM_001113498.2; = p.Y442H on NM_182830.4) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62100319; called by muse, mutect2, varscan2
- MYO10 | c.5954G>A p.R1985H | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369799275; called by muse, mutect2, varscan2
- OR5D18 | c.340T>A p.F114I | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as COSV61736553, COSV61739035; called by muse, mutect2, varscan2
- OR5H2 | c.193T>A p.Y65N | Missense Mutation (SNP) | VAF 125/398 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62350752, COSV62351215; called by muse, mutect2, varscan2
- OR5H2 | c.697A>C p.K233Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV62351229; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.679C>T p.R227C (on ENST00000259318 / NM_001136562.3; = p.R458C on NM_007203.5) | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs765001694, COSV52178386; called by muse, mutect2, varscan2
- RHPN1 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1251496710, COSV56647812; called by muse, mutect2, varscan2
- RIOK3 | c.179+1G>A p.X60_splice | Splice Site (SNP) | VAF 31/84 reads (37%) | catalogued as rs373422920; called by muse, mutect2, varscan2
- SDK2 | c.2002G>A p.V668I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs754435436, COSV66190084; called by muse, mutect2, varscan2
- SEC31A | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as COSV58876271; called by muse, mutect2, varscan2
- SLC45A4 | c.1478C>T p.T493M (on ENST00000517878 / NM_001286646.2; = p.T442M on NM_001080431.2) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs764827415, COSV50145421; called by muse, mutect2, varscan2
- SLCO2A1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761212094, COSV60487022; called by muse, mutect2, varscan2
- SYCP2 | c.642C>A p.D214E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.292); catalogued as COSV62769657; called by muse, mutect2
- SYNE2 | c.19737G>A p.M6579I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV59956727; called by muse, mutect2, varscan2
- TAF1L | c.1968A>T p.Q656H | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV54264184; called by muse, mutect2
- TRAF3IP3 | c.1520A>T p.H507L | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV50554879, COSV50558264; called by muse, mutect2, varscan2
- TRPM1 | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs372226363; called by muse, mutect2
- U2SURP | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1338299294, COSV67531892; called by muse, mutect2
- WNT9B | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs566511950, COSV51519014; called by muse, mutect2, varscan2
- ZNF423 | c.1441C>G p.Q481E (on ENST00000563137 / NM_001379286.1; = p.Q473E on NM_015069.4) | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.202); catalogued as COSV52195360; called by muse, mutect2
- FCGBP | c.10822C>T p.P3608S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, varscan2
- MED23 | c.1145del p.G382Efs*8 | Frame Shift Del (DEL) | VAF 37/113 reads (33%) | called by mutect2, pindel, varscan2
- ZNF783 | c.267del p.N90Tfs*54 | Frame Shift Del (DEL) | VAF 39/190 reads (21%) | called by mutect2, pindel, varscan2
- ACRV1 | c.747G>A p.T249= | Silent (SNP) | VAF 57/170 reads (34%) | catalogued as rs370037825; called by muse, mutect2, varscan2
- B4GALNT1 | c.828C>T p.S276= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs750756456, COSV57541889, COSV57543432; ClinVar: likely benign; called by muse, mutect2, varscan2
- DISP3 | c.1002G>A p.S334= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV53823479; called by muse, mutect2, varscan2
- ECT2L | c.1254G>A p.T418= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as rs750706600, COSV62885596; called by muse, mutect2, varscan2
- FLG | c.3843C>T p.D1281= | Silent (SNP) | VAF 128/370 reads (35%) | catalogued as rs545397624, COSV64242640; called by muse, mutect2, varscan2
- GP2 | c.1314C>A p.S438= (on ENST00000381362 / NM_001007240.3; = p.S435= on NM_001502.4) | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV56894984; called by muse, mutect2, varscan2
- GPR61 | c.396G>A p.S132= | Silent (SNP) | VAF 54/171 reads (32%) | catalogued as rs747436555, COSV68177797; called by muse, mutect2, varscan2
- KLHL13 | c.894G>A p.T298= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs377195610, COSV53249323, COSV53249754; called by muse, mutect2, varscan2
- LARP1 | c.2790G>A p.K930= (on ENST00000518297 / NM_033551.3; = p.K853= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as COSV60428563; called by muse, mutect2
- NPC1L1 | c.747C>T p.D249= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs148698796; called by muse, mutect2, varscan2
- OR5H1 | c.60A>G p.Q20= | Silent (SNP) | VAF 59/250 reads (24%) | catalogued as COSV99075115; called by muse, mutect2, varscan2
- OR7A10 | c.348C>T p.T116= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as rs757173899, COSV50166156; called by muse, mutect2, varscan2
- PACS2 | c.2376C>G p.G792= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV57653223, COSV57654824; called by muse, mutect2, varscan2
- PCDH18 | c.1320G>A p.R440= | Silent (SNP) | VAF 62/204 reads (30%) | catalogued as rs753591659, COSV61267620; called by muse, mutect2, varscan2
- PCDHA4 | c.1914C>T p.D638= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as rs781864694, COSV63539551; called by muse, mutect2, varscan2
- TTF2 | c.852G>A p.E284= | Silent (SNP) | VAF 43/161 reads (27%) | catalogued as COSV65632988; called by muse, mutect2, varscan2
- TFPI | c.628+5358G>A | Intron (SNP) | VAF 16/45 reads (36%) | catalogued as rs149480203; called by muse, mutect2, varscan2
